TCGA case TCGA-QR-A700 — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec54924b-2463-4364-a8fc-6d5a7df0b444

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,734 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 978 days (2.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dacarbazine + Vincristine; Days to treatment start: 535 days (1.5 years); Days to treatment end: 652 days (1.8 years); Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; Tissue or organ of origin: Lymph node, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 67.5 years (24,655 days); Days to diagnosis: -79 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.
3. Metastasis of diagnosis 1 (Pheochromocytoma, NOS), site: Lung, NOS. Age at diagnosis: 69.4 years (25,340 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Pheochromocytoma, NOS), site: Liver. Age at diagnosis: 69.4 years (25,340 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 606 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 606 days (1.7 years); Evidence of progression type: Convincing Image Source.
- Day 606 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 606 days (1.7 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 978 days (2.7 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-QR-A700-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A700-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A700-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Ct scan preop results: Yes; Lymph nodes examined: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lymph node(s); Other malignancy histological type: B-cell lymphoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 978 days; disease-specific survival: no event (censored), 978 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 606 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QR-A700-01A-11D-A35C-01): tumor purity 0.74, ploidy 3.01, whole-genome doublings 1.
